Somatic mutation profile of tumor specimen TCGA-BP-5006-01A (aliquot TCGA-BP-5006-01A-01D-1462-08) from TCGA case TCGA-BP-5006, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.1 years (22,324 days).
Specimen TCGA-BP-5006-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52f9b8b8-9c8e-43cb-afdf-e8944490ec37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5006-11A (Solid Tissue Normal), aliquot TCGA-BP-5006-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73fb8ad6-2eaf-4c4f-8329-b0145d3ca975

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 5, Splice Site 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs730882034, CM951275, CM982001, COSV56545134, COSV56546214, COSV56550301; ClinVar: pathogenic; called by muse, mutect2
- ARHGAP10 | c.1269T>A p.S423R | Missense Mutation (SNP) | VAF 79/311 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60598532; called by muse, mutect2, varscan2
- ASAH2 | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 211/804 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs1179980943, COSV100269896; called by muse, mutect2, varscan2
- BPIFB3 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 103/503 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs753724962, COSV64957251; called by muse, mutect2, varscan2
- CDK5RAP2 | c.695G>C p.S232T | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV62573931; called by muse, mutect2, varscan2
- CHD7 | c.6971G>A p.C2324Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV71109796; called by muse, mutect2, varscan2
- DPPA3 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as rs571145972, COSV61502979; called by muse, mutect2, varscan2
- ESPL1 | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as rs770277802, COSV57759166; called by muse, mutect2, varscan2
- FABP1 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 126/525 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV55558368, COSV55558636; called by muse, mutect2, varscan2
- FANCM | c.2626G>C p.D876H | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV57500499; called by muse, mutect2
- FASN | c.6112A>C p.N2038H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60754059; called by muse, mutect2, varscan2
- FLNA | c.1012A>C p.K338Q | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV61042166; called by muse, mutect2, varscan2
- FNDC3A | c.3093A>T p.E1031D (on ENST00000492622 / NM_001079673.2; = p.E975D on NM_014923.5) | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs778496058, COSV68132961; called by muse, mutect2, varscan2
- GRIA2 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52388872; called by muse, mutect2, varscan2
- GTPBP2 | c.860T>A p.V287D | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61076123; called by muse, mutect2, varscan2
- HSPH1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV60711238; called by muse, mutect2
- IL31RA | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51681489; called by muse, mutect2
- KLHDC10 | c.631-1G>A p.X211_splice | Splice Site (SNP) | VAF 14/72 reads (19%) | catalogued as COSV59051474, COSV59053667; called by muse, mutect2, varscan2
- METTL4 | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as COSV60603458; called by muse, mutect2, varscan2
- MFHAS1 | c.2645T>C p.I882T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV52281856; called by muse, mutect2, varscan2
- NID2 | c.1825+2T>A p.X609_splice | Splice Site (SNP) | VAF 10/142 reads (7%) | catalogued as COSV53495847; called by muse, mutect2
- P2RY14 | c.470T>C p.I157T | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV56377345; called by muse, mutect2, varscan2
- RINL | c.1461G>C p.E487D (on ENST00000591812 / NM_001195833.2; = p.E373D on NM_198445.4) | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV61574572; called by muse, mutect2, varscan2
- SCNN1B | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770978463, COSV56303921, COSV56308140; called by muse, mutect2, varscan2
- SETD2 | c.4454+1G>C p.X1485_splice | Splice Site (SNP) | VAF 30/128 reads (23%) | catalogued as COSV57436742; called by muse, mutect2
- SYCP2L | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV51649918; called by muse, mutect2, varscan2
- TYW1 | c.2181G>T p.K727N | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV62752386; called by muse, mutect2, varscan2
- WASL | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.683); catalogued as rs772484020, COSV56133425; called by mutect2, varscan2
- ADGRG4 | c.7140del p.K2380Nfs*2 | Frame Shift Del (DEL) | VAF 36/102 reads (35%) | called by mutect2, pindel, varscan2
- C2orf69 | c.795del p.G266Vfs*5 | Frame Shift Del (DEL) | VAF 35/174 reads (20%) | called by mutect2, pindel, varscan2
- GPR179 | c.4791_4820del p.V1598_T1607del (on ENST00000621958; = p.V1597_T1606del on NM_001004334.4) | In Frame Del (DEL) | VAF 38/412 reads (9%) | called by mutect2, pindel
- NMNAT3 | c.709del p.S237Vfs*84 (on ENST00000296202 / NM_001320512.1; = p.S200Vfs*84 on NM_178177.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 67/328 reads (20%) | called by mutect2, pindel, varscan2
- SPIN3 | c.587_589del p.P196del | In Frame Del (DEL) | VAF 21/52 reads (40%) | called by pindel, varscan2
- YES1 | c.724+2_724+7del p.X242_splice | Splice Site (DEL) | VAF 35/235 reads (15%) | called by mutect2, pindel, varscan2
- CRYBG1 | c.6126T>C p.C2042= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as rs1381167746, COSV64811945; called by muse, mutect2, varscan2
- GALNT10 | c.1758G>A p.Q586= | Silent (SNP) | VAF 69/265 reads (26%) | catalogued as rs774673791, COSV51725862; called by muse, mutect2, varscan2
- OTOGL | c.1617A>C p.I539= (on ENST00000547103; = p.I530= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV72006525; called by muse, mutect2, varscan2
- SEC61A1 | c.909C>T p.V303= | Silent (SNP) | VAF 34/221 reads (15%) | catalogued as COSV54576968; called by muse, mutect2, varscan2
- UNC13A | c.1464C>T p.I488= | Silent (SNP) | VAF 35/176 reads (20%) | catalogued as rs551065041, COSV53194354; called by muse, mutect2, varscan2
- NDUFA1 | c.-2A>C | 5'UTR (SNP) | VAF 62/136 reads (46%) | catalogued as COSV101007025; called by muse, mutect2, varscan2
